Surgical pathology report (de-identified scan), TCGA case TCGA-CI-6619, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-CI-6619-01B (Primary Tumor).

PREOPERATIVE DIAGNOSIS: RECTAL BLEEDING

POSTOPERATIVE DIAGNOSIS: POLYP, SEMI-CIRCUMFERENTIAL LESION IN RECTUM

TREATMENT HISTORY:

工本費の概算:

A. TRANSVERSE COLON - POLYP

2. REGION - BY DEF. REGION.

TCGA - CI - 6619

A. ADENOMATOUS POLYP, WITH LOW GRADE DYSPLASIA, TRANSVERSE COLON

H. BIOPSY SPECIMENS, REACTION, FINDINGS:

MODERATELY-DIFFERENTIATED INFILTRATING ADENOCARCINOMA

RESULTS OF COMPUTER-ASSISTED QUANTITATIVE LININGSTAINING ARE PENDING
(SEE MICROSCOPIC)

Source: NCI Genomic Data Commons file 6d9f3c6c-1b35-4198-b677-cf687965a921 (TCGA-CI-6619.9060BC33-42B3-4EE3-8137-9FE5913C480D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).